HCMI case HCM-BROD-0130-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e9615c7c-0e14-45bc-a58e-ce3afbb6d40d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1959; Vital status: Dead; Days to death: 322 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.2; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: metastasis; Age at diagnosis: 57.6 years (21,030 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: Yes; Sites of involvement: Pleura.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 6 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 6 days; Days to treatment end: 61 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine + Nab-paclitaxel; Treatment intent type: Neoadjuvant; Days to treatment start: 6 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine + Nab-paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 124 days; Days to treatment end: 236 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 262 days; Days to treatment end: 262 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Neoadjuvant.
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 0 days.
- Days to follow up: 313 days; Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- CA19-9: 90759.
- CDKN2A mutation, nos: Positive.
- TP53 mutation, nos: Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 77 kg; Height: 187 cm; BMI: 22.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Alcohol intensity: Non-Drinker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples)
- Sample HCM-BROD-0130-C25-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: Frozen.
- Sample HCM-BROD-0130-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample HCM-BROD-0130-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
